Somatic mutation profile of tumor specimen TCGA-KU-A66T-01A (aliquot TCGA-KU-A66T-01A-11D-A30E-08) from TCGA case TCGA-KU-A66T, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.1 years (19,405 days).
Specimen TCGA-KU-A66T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 788cf49a-2cb0-4f7c-8a7b-d11fa36a7fa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KU-A66T-10A (Blood Derived Normal), aliquot TCGA-KU-A66T-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c183f8bd-19d5-4cb5-bd0d-b855dd848581

The open-access MAF lists 117 somatic variants for this specimen: 88 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 28, Nonsense Mutation 8, Splice Site 3, Intron 1, Nonstop Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRWD3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as rs1057518650, COSV64748656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 34/36 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV99714627; called by muse, mutect2, varscan2
- ABCB5 | c.3382G>A p.A1128T (on ENST00000404938 / NM_001163941.2; = p.A683T on NM_178559.6) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV99329968; called by muse, mutect2, varscan2
- AC013489.1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99183907; called by muse, mutect2, varscan2
- ADCY8 | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99654676; called by muse, mutect2
- ALLC | c.248C>G p.T83R | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52994164, COSV99378331; called by muse, mutect2, varscan2
- ANKIB1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV99730044; called by muse, mutect2, varscan2
- ANKRD27 | c.1729T>C p.Y577H | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV60132342; called by muse, mutect2
- APOBEC3B | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100213876; called by muse, mutect2, varscan2
- ARHGAP36 | c.1486+2T>A p.X496_splice | Splice Site (SNP) | VAF 24/89 reads (27%) | catalogued as COSV99358295; called by muse, mutect2, varscan2
- ARMH3 | c.2012T>C p.L671P | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs754094410, COSV99493648; called by muse, mutect2, varscan2
- BMS1 | c.1895A>G p.Q632R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100996846; called by muse, mutect2, varscan2
- BRIP1 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99371225; called by muse, mutect2, varscan2
- C2CD3 | c.3512C>G p.S1171* | Nonsense Mutation (SNP) | VAF 28/436 reads (6%) | catalogued as COSV100487524; called by muse, mutect2
- CAPN7 | c.1972C>T p.Q658* | Nonsense Mutation (SNP) | VAF 72/172 reads (42%) | catalogued as COSV99513084; called by muse, mutect2, varscan2
- CASKIN1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs917862443, COSV100623845; called by muse, mutect2, varscan2
- CCDC93 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100099585; called by muse, mutect2, varscan2
- CENPE | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV99479376; called by muse, mutect2, varscan2
- CHD1 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99399411, COSV99399989; called by muse, mutect2, varscan2
- CHL1 | c.3178C>T p.Q1060* (on ENST00000397491 / NM_001253387.1; = p.Q1076* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV99852546; called by muse, mutect2, varscan2
- CSRNP2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs762864126, COSV99950538; called by muse, mutect2, varscan2
- CTAG2 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.813); catalogued as COSV55995230, COSV99909220; called by muse, mutect2, varscan2
- CUBN | c.3549G>T p.M1183I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV100913662; called by muse, mutect2, varscan2
- CUBN | c.2757T>G p.H919Q | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.178); catalogued as COSV100913663; called by muse, mutect2, varscan2
- CYFIP1 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as rs1203995382, COSV100488839; called by muse, mutect2, varscan2
- EGF | c.268T>G p.W90G | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99491428; called by muse, mutect2, varscan2
- EPB41L3 | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); catalogued as rs780565414, COSV100550504; called by muse, mutect2, varscan2
- FGF19 | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV99594453; called by muse, mutect2
- FLNA | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 73/307 reads (24%) | catalogued as COSV100775324; called by muse, mutect2, varscan2
- FTO | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101151375, COSV67110782; called by muse, mutect2, varscan2
- FUT9 | c.470C>G p.T157S | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV100134562; called by muse, mutect2, varscan2
- GOLGA8G | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100284674; called by muse, mutect2, varscan2
- GRIK2 | c.1426T>A p.F476I | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100029824; called by muse, mutect2, varscan2
- GRIN2C | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.173); catalogued as rs937774274, COSV99501546; called by muse, mutect2, varscan2
- GSPT1 | c.1366C>T p.R456C (on ENST00000420576 / NM_001130007.2; = p.R594C on NM_002094.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as rs1567434013, COSV70452830; called by muse, mutect2, varscan2
- GYPA | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.013); catalogued as COSV99302878; called by muse, mutect2
- HOOK3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 211/286 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100296119; called by muse, varscan2
- HYDIN | c.5902G>A p.V1968I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1308948704, COSV99993850; called by muse, mutect2
- IFRD1 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134444; called by muse, mutect2
- IL17B | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs140917979; called by muse, mutect2, varscan2
- IL17RA | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as rs138404135; called by muse, mutect2, varscan2
- IRX1 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs760388504, COSV57358381, COSV57358629; called by muse, mutect2
- LMTK2 | c.3272C>T p.T1091M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs61734170; called by muse, mutect2, varscan2
- LRRN4CL | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs551756407, COSV99628566; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101012245; called by muse, mutect2, varscan2
- MAST1 | c.3847C>A p.R1283S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as rs1384185419, COSV99263806; called by muse, mutect2, varscan2
- MAST3 | c.1150G>C p.V384L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99446435; called by muse, mutect2
- MECOM | c.1120G>A p.E374K (on ENST00000468789 / NM_001105078.4; = p.E562K on NM_004991.4) | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs149928659, COSV52963475; called by muse, mutect2, varscan2
- MEGF6 | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99621494; called by muse, mutect2, varscan2
- MGAT5 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776240487, COSV56100588; called by muse, mutect2, varscan2
- MINPP1 | c.786A>T p.L262F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.486); catalogued as rs768977489, COSV64354032; called by muse, mutect2, varscan2
- MS4A12 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs111546873, COSV50014503; called by muse, mutect2, varscan2
- NR1H3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774079609, COSV68008145; called by muse, mutect2, varscan2
- OR5V1 | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101011494; called by muse, mutect2
- OR8K1 | c.525T>G p.C175W | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV99687570; called by muse, mutect2, varscan2
- PABPC4 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1804943, COSV100865538; called by muse, mutect2, varscan2
- PDE3A | c.3304C>A p.Q1102K | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV100762880, COSV62973248; called by muse, mutect2, varscan2
- PIH1D1 | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV51807999, COSV99221255; called by muse, mutect2
- PIK3CD | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs573872848, COSV63128470; called by muse, mutect2, varscan2
- PLA2G1B | c.447A>C p.*149Cext*20 | Nonstop Mutation (SNP) | VAF 93/341 reads (27%) | catalogued as COSV100387573; called by muse, mutect2, varscan2
- PLCH1 | c.4798A>C p.N1600H (on ENST00000340059 / NM_001130960.2; = p.N1592H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.259); catalogued as COSV100398421; called by muse, mutect2
- PLD1 | c.2812C>G p.P938A | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as COSV100578999; called by muse, mutect2, varscan2
- PSMD12 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100635443; called by muse, mutect2, varscan2
- PTPRM | c.4102A>G p.I1368V | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0.07); catalogued as COSV100160959; called by muse, mutect2, varscan2
- RADIL | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as rs1416762237, COSV101271636; called by muse, mutect2
- RBMXL1 | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99557099; called by muse, mutect2
- RECQL | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 48/113 reads (42%) | catalogued as rs1326657671, COSV101389344; called by muse, mutect2, varscan2
- SEC63 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV64600521; called by muse, mutect2
- SEMA6A | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as rs750386162, COSV56714551; called by muse, mutect2, varscan2
- SH3GL1 | c.624+1G>T p.X208_splice | Splice Site (SNP) | VAF 24/124 reads (19%) | catalogued as COSV99515429; called by muse, mutect2, varscan2
- SH3RF1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753491215, COSV52922327; called by muse, mutect2, varscan2
- SHC2 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs769883678, COSV99199241; called by muse, mutect2
- SMURF2 | c.483C>T p.D161= | Splice Region (SNP) | VAF 27/168 reads (16%) | catalogued as rs149849389; called by muse, mutect2, varscan2
- SOWAHA | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101097745; called by muse, mutect2, varscan2
- SPDEF | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99763384; called by muse, mutect2, varscan2
- SYNE1 | c.20878A>G p.I6960V (on ENST00000367255 / NM_182961.4; = p.I6889V on NM_033071.3) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs759030278, COSV99581636; called by muse, mutect2, varscan2
- TAOK2 | c.2616G>C p.L872F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99665613; called by muse, mutect2, varscan2
- TMEM145 | c.1178C>G p.A393G | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV100004180, COSV56623866; called by muse, mutect2, varscan2
- TSPAN13 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100018209; called by muse, mutect2, varscan2
- ZFP37 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs373174435; called by muse, mutect2, varscan2
- ZMAT1 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100858958; called by muse, mutect2
- ZNF366 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100574549; called by muse, mutect2, varscan2
- ZNF445 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101253910; called by muse, mutect2, varscan2
- ZNF84 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as rs1272853787, COSV59654203; called by muse, mutect2, varscan2
- GPATCH8 | c.615_623+29del p.X205_splice | Splice Site (DEL) | VAF 16/142 reads (11%) | called by mutect2, pindel
- IGHV3-35 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 53/481 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PAX9 | c.162_169del p.K55Gfs*259 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- ANO1 | c.375C>G p.R125= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV100304581; called by muse, mutect2
- AP2M1 | c.180G>A p.R60= | Silent (SNP) | VAF 69/183 reads (38%) | catalogued as COSV99491009; called by muse, mutect2, varscan2
- BBS2 | c.969G>A p.E323= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV99802900; called by muse, mutect2, varscan2
- CFAP52 | c.876C>A p.G292= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100235633; called by muse, mutect2
- CYP4F12 | c.243G>A p.S81= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs771986037, COSV100216235; called by muse, mutect2, varscan2
- EGFR | c.1932G>C p.P644= | Silent (SNP) | VAF 32/912 reads (4%) | catalogued as COSV99295655; called by muse, mutect2
- FLT3 | c.255A>T p.V85= | Silent (SNP) | VAF 67/77 reads (87%) | catalogued as COSV99610395; called by muse, mutect2, varscan2
- FMO3 | c.1425C>T p.G475= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs779397809, COSV100882562; called by muse, mutect2, varscan2
- FZD9 | c.1494G>A p.S498= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs782046803, COSV100290149; called by muse, mutect2, varscan2
- HERC2 | c.2412C>G p.L804= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV99877287; called by muse, mutect2, varscan2
- ICAM5 | c.2076C>T p.A692= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99703572; called by muse, mutect2, varscan2
- LDOC1 | c.87G>A p.Q29= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV100983216; called by muse, mutect2, varscan2
- LHX1 | c.294C>T p.L98= | Silent (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- MIEF2 | c.984C>T p.N328= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV100544157; called by muse, varscan2
- MORF4L2 | c.276C>T p.S92= | Silent (SNP) | VAF 29/191 reads (15%) | catalogued as rs1278800477, COSV100846402; called by muse, mutect2, varscan2
- NSDHL | c.144C>T p.F48= | Silent (SNP) | VAF 92/318 reads (29%) | catalogued as rs782430721, COSV100938694; called by muse, mutect2, varscan2
- NUP93 | c.2310G>A p.S770= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs542681313, COSV100360542; called by muse, mutect2, varscan2
- NYAP1 | c.411G>A p.T137= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100278726; called by muse, mutect2, varscan2
- OTOF | c.1224G>A p.E408= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99719186; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.996G>T p.G332= (on ENST00000374531 / NM_001037293.2; = p.G364= on NM_053016.6) | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV100093769; called by muse, mutect2, varscan2
- PFAS | c.3606C>T p.Y1202= | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as rs150119860; called by muse, mutect2, varscan2
- PLEC | c.9927G>A p.S3309= (on ENST00000322810 / NM_201380.4; = p.S3199= on NM_000445.5) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs782474875, COSV59646730; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEH | c.336C>T p.S112= | Silent (SNP) | VAF 119/332 reads (36%) | catalogued as rs201370755, COSV58879719; called by muse, varscan2
- SLC6A8 | c.1113C>T p.G371= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs1411836045, COSV53472883; ClinVar: benign; called by muse, mutect2, varscan2
- SPTBN4 | c.3555C>G p.L1185= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100152289, COSV58943577; called by muse, mutect2, varscan2
- ZNF713 | c.75C>T p.A25= (on ENST00000633730 / NM_001366796.2; = p.A38= on NM_182633.3) | Silent (SNP) | VAF 66/218 reads (30%) | catalogued as rs760309131, COSV68888039; called by muse, mutect2, varscan2
- ZNF835 | c.621G>A p.T207= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101606248, COSV73379201; called by muse, mutect2, varscan2
- ZSCAN18 | c.1059C>T p.S353= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs1369809903, COSV53738448, COSV99559512; called by muse, mutect2, varscan2
- PGAP2 | c.165+6084T>G | Intron (SNP) | VAF 22/48 reads (46%) | catalogued as COSV99544638; called by muse, mutect2, varscan2
